Somatic mutation profile of tumor specimen TCGA-C5-A1MK-01A (aliquot TCGA-C5-A1MK-01A-11D-A14W-08) from TCGA case TCGA-C5-A1MK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 79.2 years (28,939 days).
Specimen TCGA-C5-A1MK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 069f487b-a547-4195-ac83-568d5a1b3108.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1MK-10A (Blood Derived Normal), aliquot TCGA-C5-A1MK-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59c2f3fd-9ea3-4c51-a972-822b535fddbd

The open-access MAF lists 339 somatic variants for this specimen: 242 protein-altering or splice-affecting, 90 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 216, Silent 90, Nonsense Mutation 20, Intron 2, 3'Flank 2, Translation Start Site 2, In Frame Del 1, Frame Shift Ins 1, RNA 1, 5'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCA12 | c.6353C>T p.S2118L (on ENST00000272895 / NM_173076.3; = p.S1800L on NM_015657.3) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV55952642; called by mutect2, varscan2
- ABCA8 | c.2896G>C p.E966Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.152); catalogued as COSV52196959; called by muse, mutect2, varscan2
- ACACB | c.3494C>T p.S1165F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV58130507; called by muse, mutect2, varscan2
- ACTL10 | c.737G>C p.*246Sext*18 | Nonstop Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV55775233; called by muse, mutect2, varscan2
- ACTN4 | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV53142627, COSV53144068; called by muse, varscan2
- ADAM10 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.216); catalogued as COSV53049978; called by muse, mutect2, varscan2
- ADAMTS1 | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53169225, COSV53170417; called by muse, mutect2, varscan2
- ADAMTS14 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV64600526; called by muse, mutect2, varscan2
- ADAMTS16 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.117); catalogued as rs374351561; called by muse, mutect2, varscan2
- ADAT1 | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV57185698; called by muse, mutect2, varscan2
- ADCY9 | c.3448G>C p.D1150H | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53572821; called by muse, mutect2, varscan2
- ADGRV1 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.147); catalogued as COSV67980755, COSV67989591; called by muse, varscan2
- AIMP2 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs1234204854, COSV56150238; called by muse, mutect2, varscan2
- AKAP1 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV58469043; called by muse, mutect2, varscan2
- AMOTL1 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.708); catalogued as COSV54414626; called by muse, mutect2, varscan2
- APBB1IP | c.1955C>G p.S652* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs777769666, COSV66131039; called by muse, mutect2, varscan2
- APOB | c.6121G>C p.E2041Q | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV51928015; called by muse, mutect2, varscan2
- AQP10 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as COSV59245278; called by muse, mutect2, varscan2
- AQP8 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV54844479; called by muse, mutect2, varscan2
- ARFGAP1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV62262596; called by muse, mutect2
- ARHGAP30 | c.2253G>C p.E751D | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.24); catalogued as COSV100920397; called by muse, mutect2
- ARID1A | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV61373914; called by muse, mutect2, varscan2
- ARID1A | c.4270C>T p.Q1424* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV61373918, COSV61374195; called by muse, mutect2, varscan2
- ATAD2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.835); catalogued as COSV54878741; called by muse, mutect2, varscan2
- ATF4 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs547982920, COSV100307533, COSV57477894; called by muse, mutect2, varscan2
- ATM | c.4310G>A p.R1437K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs1227046364, CM0910501, COSV53733363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1E2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs778583536, COSV60576132; called by muse, mutect2
- BARD1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 7/105 reads (7%) | catalogued as COSV99639308; called by muse, mutect2
- BDP1 | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV62429815; called by muse, mutect2, varscan2
- BIN1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs1385213884, COSV52116829; called by muse, mutect2, varscan2
- BMP15 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53140130; called by muse, mutect2, varscan2
- BRWD1 | c.1936G>C p.D646H | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV60893751; called by muse, mutect2, varscan2
- BSG | c.848C>G p.S283* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV61076495; called by muse, mutect2, varscan2
- C3orf14 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs567089108, COSV51706474; called by muse, mutect2
- C4B | c.3695C>T p.S1232L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1244947865, COSV70313320; called by muse, mutect2, varscan2
- CABP2 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53708473; called by muse, mutect2, varscan2
- CACNA1B | c.4916G>A p.R1639Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.49); catalogued as rs373622271; called by muse, mutect2, varscan2
- CBLC | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs770372319, COSV54321829; called by muse, mutect2, varscan2
- CBX1 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.54); catalogued as COSV56681530; called by muse, mutect2, varscan2
- CCDC110 | c.1862G>C p.R621T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.523); catalogued as COSV56869854; called by muse, mutect2, varscan2
- CCDC191 | c.1793C>G p.A598G | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as COSV55670860; called by muse, mutect2, varscan2
- CDC42BPA | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62005539; called by muse, mutect2, varscan2
- CFAP100 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV61502593; called by muse, mutect2, varscan2
- CHD7 | c.5977G>C p.D1993H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as COSV71107916; called by muse, mutect2, varscan2
- CIP2A | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55417698; called by muse, mutect2
- CLDN18 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1278153754, COSV59302005; called by muse, mutect2, varscan2
- CLEC11A | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs368757096; called by muse, mutect2, varscan2
- CLSTN3 | c.2053G>T p.D685Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV56934773; called by muse, mutect2, varscan2
- CLUL1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV58111569; called by muse, mutect2, varscan2
- CNTRL | c.4258G>C p.E1420Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53044877; called by muse, mutect2, varscan2
- COX4I2 | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV65781716; called by muse, mutect2
- CTNNA3 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57717993; called by muse, mutect2, varscan2
- CXorf21 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 25/153 reads (16%) | catalogued as COSV66762543; called by muse, mutect2, varscan2
- DCAF6 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.242); catalogued as rs745578537, COSV56576236; called by muse, mutect2
- DCP1A | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs115623412; called by muse, varscan2
- DDHD1 | c.1618G>A p.E540K (on ENST00000323669; = p.E737K on NM_030637.3) | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as COSV60357096, COSV60357927; called by muse, mutect2, varscan2
- DGCR8 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV61226007; called by muse, mutect2, varscan2
- DLG3 | c.1420G>C p.E474Q (on ENST00000374360 / NM_021120.4; = p.E137Q on NM_020730.3) | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV52080680; called by muse, mutect2, varscan2
- DMXL1 | c.8266C>G p.L2756V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV60707136; called by muse, mutect2, varscan2
- DNAH2 | c.8404A>T p.K2802* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV66717679; called by muse, mutect2
- DNAH9 | c.3343G>A p.V1115I | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as rs143003954; called by muse, mutect2, varscan2
- DNAJB6 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.65); catalogued as COSV51094670; called by muse, mutect2, varscan2
- DNAJC16 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV65448242; called by muse, mutect2, varscan2
- DOCK10 | c.1584G>C p.K528N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV51359944; called by muse, mutect2
- DSCAM | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182107464, COSV68023174, COSV68028509; called by muse, mutect2
- DUOXA1 | c.965C>G p.S322* | Nonsense Mutation (SNP) | VAF 15/134 reads (11%) | catalogued as COSV50993241; called by muse, mutect2, varscan2
- DUSP15 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs773523717, COSV54065377; called by muse, mutect2, varscan2
- DUSP5 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV63645422, COSV63645794; called by muse, mutect2, varscan2
- EIF5B | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.073); catalogued as rs1291180571, COSV56811718; called by muse, mutect2, varscan2
- EPB41L1 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV52435255; called by muse, mutect2, varscan2
- EPHA5 | c.1981C>T p.Q661* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as COSV56636204; called by muse, mutect2, varscan2
- ERICH3 | c.3745G>A p.D1249N | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1263135564, COSV58601987, COSV58621197; called by muse, mutect2, varscan2
- EXOSC1 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.278); catalogued as rs762016854, COSV61748871; called by muse, mutect2, varscan2
- FAM217B | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as COSV62564032; called by muse, mutect2, varscan2
- FAT3 | c.7945G>A p.D2649N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1162671325, COSV53088584; called by muse, mutect2, varscan2
- FBXO33 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV53233641; called by muse, mutect2, varscan2
- FETUB | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54005119; called by muse, mutect2, varscan2
- FILIP1 | c.3100C>T p.R1034W | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201283216; called by muse, mutect2, varscan2
- FLT1 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs373801409; called by muse, mutect2, varscan2
- FNDC1 | c.5231C>T p.S1744L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369189702; called by muse, mutect2, varscan2
- FRMPD3 | c.1637C>G p.S546W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99346321, COSV99346763; called by muse, mutect2, varscan2
- GBF1 | c.4573G>C p.E1525Q (on ENST00000369983 / NM_001377137.1; = p.E1524Q on NM_004193.3) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV64143582; called by muse, mutect2, varscan2
- GCN1 | c.4779G>C p.Q1593H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV56105212; called by muse, mutect2, varscan2
- GFPT1 | c.1210C>G p.Q404E (on ENST00000357308 / NM_001244710.2; = p.Q386E on NM_002056.4) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); catalogued as COSV61947073; called by muse, mutect2, varscan2
- GIGYF1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1440155839, COSV51940161; called by muse, mutect2, varscan2
- GK5 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as COSV67485422; called by muse, mutect2, varscan2
- GNA11 | c.168C>G p.I56M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50017995; called by muse, mutect2, varscan2
- GPAT4 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs765596568, COSV67840316; called by muse, mutect2, varscan2
- GPR34 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100587164, COSV100587536; called by muse, mutect2
- H3C6 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as rs1343949085; called by muse, mutect2
- HAP1 | c.1786G>A p.E596K (on ENST00000310778 / NM_001367460.1; = p.E544K on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/337 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV100169874, COSV57877777, COSV57878265; called by muse, mutect2, varscan2
- HCN1 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV57499168; called by muse, mutect2, varscan2
- HEATR1 | c.6060G>A p.M2020I | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV63980047; called by muse, mutect2
- HFM1 | c.3433C>T p.H1145Y | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54023650, COSV99645804; called by muse, mutect2, varscan2
- HFM1 | c.3323G>C p.R1108T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV54023659; called by muse, mutect2, varscan2
- HIPK1 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61246662; called by muse, mutect2, varscan2
- HIPK1 | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV61246682, COSV61248951; called by muse, mutect2, varscan2
- HMCN1 | c.10412G>A p.R3471K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1403340449, COSV54885550; called by muse, mutect2, varscan2
- HUWE1 | c.8822G>A p.R2941Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1410756224, COSV53338619; called by muse, mutect2, varscan2
- IGFN1 | c.2218C>T p.P740S (on ENST00000295591 / NM_001367841.1; = p.P3197S on NM_001164586.2) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as rs766538758, COSV55168494; called by muse, mutect2, varscan2
- IGSF22 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV60031964, COSV60039383; called by muse, mutect2, varscan2
- IL17C | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54918286; called by muse, mutect2, varscan2
- INO80E | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs1173098156, COSV58750877; called by muse, mutect2, varscan2
- IPO5 | c.1241G>C p.R414T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152926; called by muse, mutect2, varscan2
- IQCH | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV60050463; called by muse, mutect2, varscan2
- IRAG1 | c.2395C>G p.Q799E | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV70210350; called by muse, mutect2, varscan2
- ITK | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.285); catalogued as COSV68435264, COSV68435480; called by muse, mutect2
- KCNJ11 | c.501C>G p.I167M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.953); catalogued as COSV60594334; called by muse, mutect2, varscan2
- KCNJ16 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1228542561, COSV52251555; called by muse, mutect2, varscan2
- KDM5B | c.4409C>G p.S1470* | Nonsense Mutation (SNP) | VAF 37/204 reads (18%) | catalogued as COSV52505600, COSV99349892; called by muse, mutect2, varscan2
- KIF20B | c.3352G>C p.E1118Q (on ENST00000371728 / NM_001284259.2; = p.E1078Q on NM_016195.4) | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV53304301; called by muse, mutect2, varscan2
- KIF23 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1185943733, COSV52978100; called by muse, mutect2, varscan2
- KIF2C | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV64764060, COSV64764146; called by muse, mutect2, varscan2
- KLHL2 | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56975003; called by muse, mutect2, varscan2
- KRT15 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 66/291 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54178635; called by muse, mutect2, varscan2
- KY | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.331); catalogued as rs867415790, COSV101415019; called by muse, mutect2
- LACC1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57828799; called by muse, mutect2, varscan2
- LENG8 | c.1708C>G p.P570A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.642); catalogued as rs1220119231, COSV100417876, COSV58726624, COSV58727305; called by muse, mutect2
- LONRF2 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs760683755, COSV66539800; called by muse, mutect2, varscan2
- LOXL3 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as COSV51206487; called by muse, mutect2, varscan2
- LRP5 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs184945579, COSV99592397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRK1 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV52605162; called by muse, mutect2, varscan2
- LRRK1 | c.4625C>G p.S1542* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV52605194; called by muse, mutect2, varscan2
- LRRN1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs547803135, COSV60013022; called by muse, mutect2, varscan2
- MAML3 | c.3381G>C p.W1127C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101558374, COSV72208767; called by muse, mutect2, varscan2
- MAPK7 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55189761; called by muse, mutect2, varscan2
- MGAT4C | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.052); catalogued as COSV59830943, COSV59831532; called by muse, mutect2, varscan2
- MGAT4C | c.867G>T p.L289F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59830952; called by muse, mutect2, varscan2
- MROH8 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54118391; called by muse, mutect2, varscan2
- MSMO1 | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1235904879, COSV54969839; called by muse, mutect2, varscan2
- MTRF1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.532); catalogued as rs761757522, COSV65263087; called by muse, mutect2, varscan2
- MUC16 | c.26728C>T p.P8910S | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV67453315; called by muse, mutect2, varscan2
- MYH1 | c.4352G>A p.R1451K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV99875557; called by muse, mutect2
- MYH1 | c.1929G>C p.K643N | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV56845250, COSV56856418; called by muse, mutect2, varscan2
- MYH2 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV55433784; called by muse, mutect2, varscan2
- MYH8 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV67961631; called by muse, mutect2, varscan2
- MYH9 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV53383429; called by muse, mutect2, varscan2
- NAV3 | c.5294C>T p.S1765L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs761133141, COSV57068073; called by muse, mutect2, varscan2
- NBAS | c.4855G>A p.E1619K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs145651640; called by muse, mutect2, varscan2
- NBEAL1 | c.7564C>T p.Q2522* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV68915740; called by muse, mutect2, varscan2
- NCAPH2 | c.1039C>G p.L347V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV52686946; called by muse, mutect2, varscan2
- NCKAP1 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV62940274; called by muse, mutect2, varscan2
- NCSTN | c.375G>C p.L125F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV54186199; called by muse, mutect2, varscan2
- NIPBL | c.7889C>T p.P2630L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV56945867; called by mutect2, varscan2
- NSD3 | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.952); catalogued as COSV57617720; called by muse, mutect2, varscan2
- NUMA1 | c.3560C>T p.S1187L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs749408043, COSV61184030, COSV61187507; called by muse, mutect2, varscan2
- NUP107 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as rs1341739376, COSV57493747; called by muse, mutect2, varscan2
- NUP62 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV61311269; called by muse, mutect2, varscan2
- NUP62 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV61311277, COSV61312423; called by muse, mutect2, varscan2
- OPRL1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs762717438, CM124622, COSV61091043, COSV61091174; called by muse, mutect2, varscan2
- OR13C9 | c.885C>G p.I295M | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52241126, COSV99403524; called by muse, mutect2, varscan2
- OR2G2 | c.840C>G p.F280L | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV100190005, COSV60739800; called by muse, mutect2, varscan2
- OR4L1 | c.59G>C p.R20P | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59849231, COSV59851325; called by muse, mutect2, varscan2
- OR5H1 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV63401984; called by muse, mutect2, varscan2
- PBLD | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53265496; called by muse, mutect2, varscan2
- PCDHB3 | c.2329C>G p.Q777E | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1287905869, COSV50566011; called by muse, mutect2, varscan2
- PIK3CD | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63127611; called by muse, mutect2, varscan2
- PKN3 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV52575550; called by muse, mutect2, varscan2
- PLCB2 | c.3174G>T p.M1058I | Missense Mutation (SNP) | VAF 81/455 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV53031779; called by muse, mutect2, varscan2
- PLEKHA1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.411); catalogued as rs374805648; called by muse, mutect2, varscan2
- PLEKHG3 | c.2362G>A p.E788K (on ENST00000394691; = p.E844K on NM_001308147.2) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1397816729, COSV55978406; called by muse, mutect2, varscan2
- PLEKHG3 | c.2715G>C p.K905N (on ENST00000394691; = p.K961N on NM_001308147.2) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.167); catalogued as COSV55978429; called by muse, mutect2, varscan2
- PLEKHG4 | c.2052G>C p.Q684H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as COSV58571631; called by muse, mutect2, varscan2
- PRDM16 | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54583252; called by muse, mutect2, varscan2
- PRG4 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs267598237, COSV63355121; called by muse, varscan2
- PRKAR2B | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99708479; called by muse, mutect2
- PROX1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.963); catalogued as COSV54777025; called by muse, mutect2, varscan2
- PROX1 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as COSV54777035; called by muse, mutect2, varscan2
- PROX1 | c.1464G>C p.L488F | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV54777043; called by muse, mutect2, varscan2
- PRR7 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52788296; called by muse, mutect2, varscan2
- PTCD1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs534734137, COSV52858613; called by muse, varscan2
- PTPRF | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1455359848, COSV63444237; called by muse, mutect2
- PYROXD1 | c.1368G>A p.M456I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1001883622, COSV53708674; called by muse, mutect2, varscan2
- RANBP6 | c.1853G>C p.R618T | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52388582; called by muse, mutect2, varscan2
- RASSF2 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.198); catalogued as COSV65081869, COSV65083457; called by muse, mutect2, varscan2
- RBM26 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV57392542; called by muse, varscan2
- RHBDF1 | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs772594707, COSV51954064; called by muse, mutect2, varscan2
- RNF151 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV58399451; called by muse, mutect2
- ROCK1 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 37/151 reads (25%) | catalogued as COSV67694996; called by muse, mutect2, varscan2
- RSF1 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); catalogued as COSV57837635; called by muse, mutect2, varscan2
- RTN4 | c.2944C>T p.P982S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV58265731; called by muse, mutect2, varscan2
- RTN4 | c.2195C>G p.S732C | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV58265749; called by muse, mutect2, varscan2
- SCN5A | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.396); catalogued as COSV60067093; called by muse, mutect2, varscan2
- SCNN1D | c.914G>A p.G305D (on ENST00000338555; = p.G469D on NM_001130413.4) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs1470728736, COSV57640536; called by muse, mutect2
- SEC14L4 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV55398898; called by muse, mutect2, varscan2
- SFN | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.369); catalogued as rs753008567, COSV59433041; called by muse, mutect2, varscan2
- SIGLEC10 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV59479895; called by muse, mutect2, varscan2
- SIGMAR1 | c.338C>G p.S113C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52844501, COSV99449590; called by muse, mutect2, varscan2
- SLC33A1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV63946831; called by muse, mutect2, varscan2
- SLC39A10 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs867101036, COSV100660695; called by muse, mutect2, varscan2
- SLC9A7 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as rs771899348, COSV60378759; called by muse, mutect2, varscan2
- SLFN11 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV57698013; called by muse, mutect2, varscan2
- SLITRK5 | c.1584G>C p.L528F | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.58); catalogued as COSV61521607; called by muse, mutect2, varscan2
- SMARCAL1 | c.2808G>C p.Q936H | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as COSV61920343; called by muse, mutect2, varscan2
- SMC2 | c.1367G>A p.R456K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53956197; called by muse, mutect2, varscan2
- SMC4 | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV59086721; called by muse, mutect2, varscan2
- SNX29 | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV60053995; called by muse, mutect2
- SPHKAP | c.4632G>T p.M1544I | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV60872141, COSV60889967; called by muse, mutect2, varscan2
- STK16 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373913851, COSV50277860; called by muse, mutect2, varscan2
- SUGCT | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV59320113; called by muse, mutect2, varscan2
- SV2B | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.723); catalogued as COSV100370819; called by muse, mutect2, varscan2
- SYNDIG1L | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV59047164; called by muse, mutect2, varscan2
- TAB2 | c.1241G>C p.G414A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.495); catalogued as rs775633022, COSV53851527; called by muse, mutect2, varscan2
- TCP11L1 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV57514420; called by muse, mutect2, varscan2
- TLR2 | c.1418C>G p.S473C | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV52605477; called by muse, mutect2, varscan2
- TMCO6 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV52799281; called by muse, mutect2, varscan2
- TNIK | c.3697C>T p.H1233Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52676935; called by muse, mutect2, varscan2
- TP53BP1 | c.2264G>T p.S755I | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55497962; called by muse, mutect2, varscan2
- TRAF3 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as rs1280119958, COSV61024199; called by muse, mutect2, varscan2
- TRIM37 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.387); catalogued as COSV51882367; called by muse, mutect2, varscan2
- TSSK6 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV53062900; called by muse, mutect2, varscan2
- TTN | c.95222C>T p.S31741L (on ENST00000591111; = p.S24317L on NM_003319.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | PolyPhen probably damaging (0.996); catalogued as rs1212699230, COSV100622045; called by muse, mutect2, varscan2
- TYSND1 | c.1545C>G p.F515L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767846561, COSV54642491; called by muse, mutect2, varscan2
- UBR4 | c.14665G>C p.D4889H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64384772; called by muse, mutect2, varscan2
- UBR5 | c.4861G>A p.E1621K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55282654; called by muse, mutect2, varscan2
- UPF3A | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60894585; called by muse, mutect2, varscan2
- UPK3A | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53414056; called by muse, mutect2, varscan2
- UPP2 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as rs769538423, COSV50046533; called by muse, mutect2, varscan2
- UQCRC2 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV51671285; called by muse, mutect2, varscan2
- UTP14C | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs764932517, COSV73000607; called by muse, mutect2, varscan2
- VPS25 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53820230; called by muse, mutect2, varscan2
- VPS52 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as COSV71403426; called by muse, varscan2
- XPO1 | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV68945083; called by muse, mutect2, varscan2
- YTHDC1 | c.2030G>C p.R677T (on ENST00000344157 / NM_001031732.4; = p.R659T on NM_133370.4) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1451103337, COSV60009271; called by muse, varscan2
- YTHDC1 | c.1504C>G p.Q502E (on ENST00000344157 / NM_001031732.4; = p.Q484E on NM_133370.4) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV60009280; called by muse, mutect2, varscan2
- ZC3H11A | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV59745020; called by muse, mutect2, varscan2
- ZDBF2 | c.2377G>C p.D793H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV65623148; called by muse, mutect2, varscan2
- ZHX3 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58381825; called by muse, mutect2, varscan2
- ZIM2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55628677; called by muse, mutect2
- ZNF266 | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV63221666; called by muse, mutect2, varscan2
- ZNF283 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV61030725; called by muse, varscan2
- ZNF283 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV61030732; called by muse, varscan2
- ZNF442 | c.1106G>C p.R369T | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV54420869, COSV54421378; called by muse, mutect2, varscan2
- ZNF660 | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.266); catalogued as COSV59548690; called by muse, mutect2, varscan2
- ZPBP2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.478); catalogued as COSV53100600; called by muse, mutect2, varscan2
- BCCIP | c.366_368del p.D122del | In Frame Del (DEL) | VAF 26/140 reads (19%) | called by mutect2, pindel, varscan2
- LRP6 | c.3508dup p.I1170Nfs*2 | Frame Shift Ins (INS) | VAF 38/190 reads (20%) | called by pindel, varscan2
- ROCK1 | c.2144-1G>A p.X715_splice | Splice Site (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2
- TRBV30 | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- TRDV2 | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ACOX2 | c.945C>T p.I315= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs758364833, COSV57147991; called by muse, mutect2, varscan2
- ACTN4 | c.2496C>T p.I832= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs775098041, COSV53144054; called by muse, varscan2
- ADAMTS4 | c.1014C>G p.V338= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV63487470, COSV63488559; called by muse, mutect2, varscan2
- ADGRV1 | c.18747G>A p.L6249= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV67980759; called by muse, mutect2
- ANKS6 | c.981G>A p.A327= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs745337335, COSV62049447; called by muse, mutect2, varscan2
- ARHGEF3 | c.1056C>T p.F352= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs1448641312, COSV56324500; called by muse, mutect2, varscan2
- ASH1L | c.7431G>A p.K2477= (on ENST00000368346 / NM_001366177.2; = p.K2472= on NM_018489.3) | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV64206442; called by muse, mutect2, varscan2
- ATAD3B | c.606C>T p.L202= (on ENST00000308647; = p.L308= on NM_031921.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV58019584; called by muse, mutect2, varscan2
- AVPR1A | c.603C>T p.R201= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV54545904; called by muse, mutect2, varscan2
- C2orf76 | c.264C>G p.L88= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV58345799; called by muse, mutect2, varscan2
- CD48 | c.450G>A p.L150= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as COSV63566228; called by muse, mutect2, varscan2
- CDH3 | c.1827C>T p.F609= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV50555604; called by muse, mutect2, varscan2
- CHUK | c.1866C>T p.L622= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV64917462; called by muse, mutect2, varscan2
- CNKSR3 | c.1569G>A p.G523= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV70480861; called by muse, mutect2, varscan2
- CRH | c.423C>G p.L141= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV52541889, COSV52542039; called by muse, mutect2, varscan2
- CYP11A1 | c.573C>T p.S191= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs776643277, COSV51433838; ClinVar: likely benign; called by muse, mutect2, varscan2
- DMRT2 | c.612C>G p.A204= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs776244117, COSV52401228; called by muse, varscan2
- DNAJC13 | c.1920C>T p.L640= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV53447477; called by muse, mutect2, varscan2
- DOCK1 | c.4485G>A p.E1495= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV54733502; called by muse, mutect2
- DOCK8 | c.3810G>A p.L1270= | Silent (SNP) | VAF 58/266 reads (22%) | catalogued as COSV66618717; called by muse, mutect2, varscan2
- ENPP4 | c.123G>A p.L41= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV58088520; called by muse, mutect2, varscan2
- EXPH5 | c.5874C>T p.I1958= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV56200028; called by muse, mutect2, varscan2
- F3 | c.876G>A p.L292= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV61844762; called by muse, mutect2, varscan2
- FAM47A | c.855G>A p.K285= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs778710031, COSV60495061; called by muse, mutect2, varscan2
- FARP1 | c.2268G>A p.P756= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as rs149797871; called by muse, mutect2, varscan2
- GALNT18 | c.828C>T p.I276= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV57145770; called by muse, mutect2, varscan2
- GRIN3B | c.2349C>T p.L783= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs764089467, COSV52259084; called by muse, mutect2, varscan2
- HIVEP2 | c.2169C>T p.I723= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV50006993, COSV99173830; called by muse, mutect2, varscan2
- HKDC1 | c.279G>A p.L93= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as rs778712925, COSV63576059; called by muse, mutect2, varscan2
- INCENP | c.2604C>G p.L868= (on ENST00000394818 / NM_001040694.2; = p.L864= on NM_020238.3) | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV53914126; called by muse, mutect2, varscan2
- INSIG1 | c.267C>G p.L89= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV60920003; called by muse, mutect2
- IPO7 | c.156G>C p.V52= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV65684546; called by muse, mutect2, varscan2
- IPO9 | c.2763C>T p.I921= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV64233140; called by muse, varscan2
- ITIH1 | c.2514C>T p.I838= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs143276781, COSV56254113; called by muse, mutect2, varscan2
- KBTBD12 | c.771C>T p.I257= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as rs1235081490, COSV59678227; called by muse, mutect2, varscan2
- KCNC1 | c.768C>T p.F256= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as COSV56392591; called by muse, mutect2, varscan2
- KCNQ3 | c.159C>T p.V53= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV66466108; called by muse, mutect2
- KDM5C | c.2067C>T p.I689= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV64763542; called by muse, mutect2, varscan2
- LNX2 | c.2013G>A p.L671= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV60334795; called by muse, mutect2, varscan2
- LRP1B | c.9303C>G p.L3101= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV67198113; called by muse, mutect2, varscan2
- MACF1 | c.20031G>A p.V6677= (on ENST00000372915; = p.V4722= on NM_012090.5) | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV99245811; called by muse, mutect2, varscan2
- MADD | c.69G>A p.P23= | Silent (SNP) | VAF 41/187 reads (22%) | catalogued as rs200598460, COSV60621685; called by muse, mutect2, varscan2
- MTMR8 | c.1791G>A p.Q597= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100878496; called by muse, mutect2, varscan2
- MUC6 | c.3594G>A p.P1198= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as rs373111391; called by muse, mutect2, varscan2
- MYH1 | c.4353G>A p.R1451= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV56844405; called by muse, mutect2
- MYH4 | c.1809C>G p.P603= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs1397971569, COSV55114385; called by muse, mutect2, varscan2
- MYH9 | c.663C>T p.F221= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs375965637; called by muse, mutect2, varscan2
- NDNF | c.951C>T p.V317= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV65632896, COSV65633104; called by muse, mutect2, varscan2
- NOP58 | c.627G>A p.Q209= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs947801696, COSV51895965; called by muse, mutect2, varscan2
- OBSCN | c.22848C>T p.L7616= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as rs113725359, COSV100804869; called by muse, mutect2, varscan2
- OR14A16 | c.420C>G p.V140= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs749856984, COSV100713816; called by muse, mutect2
- PAN2 | c.100C>T p.L34= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV57753161; called by muse, mutect2, varscan2
- PBLD | c.858G>A p.L286= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV53265481; called by muse, mutect2, varscan2
- PBX2 | c.1125C>T p.L375= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV66708756; called by muse, mutect2, varscan2
- PCDHA2 | c.2193G>A p.A731= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs1554120315, COSV65365667; called by muse, mutect2, varscan2
- PCDHGB7 | c.366G>T p.V122= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV53915815; called by muse, mutect2, varscan2
- PELP1 | c.2232G>A p.G744= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1365456772, COSV52586587; called by mutect2, varscan2
- PITX3 | c.516C>T p.F172= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV64174114; called by muse, varscan2
- PLEKHA7 | c.360C>T p.V120= | Silent (SNP) | VAF 40/227 reads (18%) | catalogued as COSV63044545; called by muse, mutect2, varscan2
- PRAMEF18 | c.156G>A p.L52= | Silent (SNP) | VAF 47/505 reads (9%) | called by muse, mutect2
- PSMD13 | c.699G>C p.L233= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100728869; called by muse, mutect2, varscan2
- PTGDR | c.510C>T p.G170= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as rs753210764, COSV60093332; called by muse, mutect2, varscan2
- PTPRB | c.3537C>T p.L1179= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV54236343; called by muse, mutect2, varscan2
- PTPRT | c.3738C>T p.F1246= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs750078390, COSV61967976; called by muse, mutect2, varscan2
- RAB35 | c.135C>T p.F45= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV57567322, COSV57567659; called by muse, mutect2, varscan2
- RAP2B | c.306C>T p.R102= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs751116336, COSV60256862; called by muse, mutect2, varscan2
- RNF167 | c.867A>G p.Q289= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as rs752769089, COSV99337488; called by muse, mutect2, varscan2
- RYR2 | c.12555G>A p.K4185= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs768462643, COSV63671432, COSV63674512; called by muse, mutect2, varscan2
- SART3 | c.321C>T p.I107= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV57206164; called by muse, mutect2, varscan2
- SEMA6D | c.813G>A p.E271= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as COSV60374332; called by muse, mutect2, varscan2
- SF3A3 | c.772C>T p.L258= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100885697, COSV65955564; called by muse, mutect2, varscan2
- SH3KBP1 | c.483G>A p.E161= | Silent (SNP) | VAF 35/170 reads (21%) | catalogued as COSV65639970; called by muse, mutect2, varscan2
- SLC15A1 | c.984G>C p.V328= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV64730419; called by muse, mutect2, varscan2
- SLC25A12 | c.1525C>T p.L509= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV55532141, COSV55533153; called by muse, mutect2, varscan2
- SLC38A10 | c.1179C>T p.T393= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV55843683; called by muse, mutect2
- SLC38A7 | c.291C>T p.I97= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54702608; called by muse, mutect2, varscan2
- SPC24 | c.474G>A p.G158= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV101375720; called by muse, mutect2, varscan2
- STK10 | c.387C>T p.L129= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV51571580; called by muse, mutect2, varscan2
- STON1 | c.1168C>T p.L390= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs745731216, COSV59126289, COSV59126311; called by muse, mutect2, varscan2
- SUZ12 | c.657C>G p.L219= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV59498719; called by muse, mutect2, varscan2
- TEX14 | c.3528G>A p.L1176= (on ENST00000240361 / NM_001201457.2; = p.L1130= on NM_031272.5) | Silent (SNP) | VAF 15/247 reads (6%) | catalogued as COSV99542955; called by muse, mutect2
- TMEM255B | c.159G>A p.V53= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100943254; called by muse, mutect2, varscan2
- TNFAIP6 | c.453C>T p.F151= | Silent (SNP) | VAF 42/156 reads (27%) | catalogued as COSV54640275; called by muse, mutect2, varscan2
- VIP | c.390C>T p.F130= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as rs759637289, COSV100923953; called by muse, mutect2, varscan2
- WDR7 | c.3664C>T p.L1222= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as COSV99589950; called by muse, mutect2, varscan2
- WDR83 | c.525G>C p.V175= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1362245515, COSV52952676, COSV99269680; called by muse, mutect2
- ZC3H11A | c.2058C>T p.L686= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV59746440; called by muse, mutect2, varscan2
- ZNF419 | c.360C>G p.L120= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV55658336, COSV55662234; called by muse, mutect2, varscan2
- ZNF600 | c.1941C>T p.F647= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as rs1319977612, COSV57741819; called by muse, mutect2, varscan2
- ZZEF1 | c.2380C>T p.L794= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV101068209, COSV67556379; called by muse, mutect2, varscan2
- AC024940.1 | n.5040G>A | RNA (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- ATP8B2 | c.1133+111C>T | Intron (SNP) | VAF 17/127 reads (13%) | catalogued as COSV59245287; called by muse, mutect2, varscan2
- ERH | c.-1G>C | 5'UTR (SNP) | VAF 11/33 reads (33%) | catalogued as COSV50362178, COSV50362401; called by muse, mutect2, varscan2
- PRR12 | chr19:49595070 C>G | 5'Flank (SNP) | VAF 4/24 reads (17%) | catalogued as COSV55869770; called by muse, mutect2
- RN7SL262P | chrX:49157325 C>T | 3'Flank (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- SCAI | c.99-10014C>T | Intron (SNP) | VAF 12/59 reads (20%) | catalogued as COSV60609992; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928738 G>A | 3'Flank (SNP) | VAF 25/106 reads (24%) | catalogued as rs1225690773, COSV60484315; called by muse, mutect2, varscan2
